Gene-level copy-number profile of tumor specimen RC-B65J-TMP1-A from RC case RC-B65J, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatosplenic T-cell lymphoma; Tissue or organ of origin: Unknown primary site; Age at diagnosis: 39.1 years (14,293 days).
Specimen RC-B65J-TMP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow Components NOS; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 37f7e1a0-e0c5-4cc4-aa61-f55a0296785b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator RC-B65J-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/2db2ad97-22ac-4cba-8aeb-9896f9ed8ce2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 105; copy number 1: 323; copy number 2: 57,934; copy number 3: 33; copy number 4: 2.

Homozygous deletions (total copy number 0; autosomes only): 105 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,239,580–38,340,998, 17 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr14:22,163,238–22,552,156, 88 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 323. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
